Somatic mutation profile of tumor specimen TCGA-13-0913-01A (aliquot TCGA-13-0913-01A-01W-0420-08) from TCGA case TCGA-13-0913, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.6 years (19,573 days).
Specimen TCGA-13-0913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1335d156-63c0-435f-8214-dca4c78b8033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0913-10A (Blood Derived Normal), aliquot TCGA-13-0913-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efeec14f-3ca2-48d6-a5b7-4c7cc04b4807

The open-access MAF lists 123 somatic variants for this specimen: 99 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 23, Frame Shift Ins 7, Frame Shift Del 7, In Frame Del 6, Nonsense Mutation 3, Splice Site 3, Intron 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 238/266 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.523A>C p.K175Q | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV66106557; called by muse, mutect2, varscan2
- ABCA4 | c.2342C>A p.A781D | Missense Mutation (SNP) | VAF 159/426 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV64674489; called by muse, mutect2, varscan2
- AC092143.1 | c.1295T>C p.F432S | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59248064; called by muse, mutect2, varscan2
- ADAMTS14 | c.1895A>T p.H632L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV64603356; called by muse, mutect2
- ARMCX2 | c.947_969del p.G316Vfs*3 | Frame Shift Del (DEL) | VAF 149/337 reads (44%) | catalogued as COSV57530462; called by mutect2, pindel, varscan2
- ASCC3 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.476); catalogued as rs867866801, COSV61230041; called by muse, mutect2, varscan2
- BTG1 | c.473C>G p.T158R | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs544927217, COSV99755291, COSV99755427; called by muse, mutect2, varscan2
- CEP290 | c.5759C>G p.A1920G | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs1565812995, COSV58352878; called by muse, mutect2, varscan2
- CLC | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 474/1173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376785804; called by muse, mutect2, varscan2
- CLCN5 | c.2157G>T p.L719F | Missense Mutation (SNP) | VAF 194/475 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1557194886, COSV56584897; called by muse, mutect2, varscan2
- CNGA3 | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV55625228, COSV55626836; called by muse, mutect2, varscan2
- COX11 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 66/76 reads (87%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV54803228; called by muse, mutect2, varscan2
- CYBB | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 289/678 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101059726; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs756156984; called by mutect2, varscan2
- DLX6 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50295107; called by muse, mutect2, varscan2
- DNAH1 | c.10027C>G p.L3343V | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV70234704; called by muse, mutect2, varscan2
- DNAH1 | c.11431G>A p.V3811M | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as COSV56235792; called by muse, mutect2, varscan2
- DYNC2I1 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV68105388; called by muse, mutect2, varscan2
- DYTN | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71513308; called by muse, mutect2, varscan2
- ERBIN | c.597+2T>A p.X199_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV52319418; called by muse, mutect2, varscan2
- ETAA1 | c.1889G>C p.S630T | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV55473645; called by muse, varscan2
- FAT3 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53083019; called by muse, mutect2, varscan2
- FGD1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs1388280500, COSV64308965; called by muse, mutect2, varscan2
- FLNC | c.6795G>T p.E2265D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV57966985; called by muse, mutect2
- FZD2 | c.164C>G p.T55S | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100190332; called by muse, mutect2
- GATAD2A | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV53071618; called by mutect2, varscan2
- GCNA | c.1594T>A p.S532T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.16); catalogued as COSV65467250; called by muse, mutect2, varscan2
- GGT5 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 130/207 reads (63%) | SIFT tolerated (0.45); PolyPhen benign (0.23); catalogued as rs1183659624, COSV54070879; called by muse, mutect2, varscan2
- GNAS | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 96/403 reads (24%) | catalogued as CM002274, COSV55677028; called by muse, mutect2, varscan2
- GNS | c.1188A>C p.L396F | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99253704; called by muse, mutect2, varscan2
- GPR37L1 | c.974_982del p.T325_C328delinsS | In Frame Del (DEL) | VAF 28/94 reads (30%) | catalogued as COSV66162446; called by mutect2, pindel, varscan2
- H2AJ | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as COSV63762171; called by muse, mutect2, varscan2
- HTR4 | c.869C>G p.P290R | Missense Mutation (SNP) | VAF 131/286 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58797734; called by muse, mutect2, varscan2
- IGSF1 | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 313/995 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV63838181; called by muse, mutect2, varscan2
- IL4R | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV50148144; called by muse, mutect2, varscan2
- IL7R | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 496/1076 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as CX118705, COSV100286722, COSV57409589; called by muse, mutect2, varscan2
- LCE2C | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as COSV64228472; called by muse, mutect2, varscan2
- LMNA | c.1740C>A p.N580K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV61543244; called by muse, mutect2, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 18/162 reads (11%) | catalogued as rs750932259; called by mutect2, varscan2
- MB21D2 | c.1301C>G p.T434S | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66664131; called by muse, mutect2, varscan2
- MTCL1 | c.4763C>T p.S1588F (on ENST00000306329 / NM_001378206.1; = p.S1269F on NM_015210.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60407369; called by muse, mutect2, varscan2
- MUC16 | c.8047G>A p.E2683K | Missense Mutation (SNP) | VAF 293/341 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67473473, COSV67479670; called by muse, mutect2, varscan2
- MYH7 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 269/656 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs727503278, CM032601, CM034049, COSV62520487; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYPN | c.3114T>G p.S1038R | Missense Mutation (SNP) | VAF 208/548 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV62734994; called by muse, mutect2, varscan2
- ODF2L | c.1418C>T p.T473M (on ENST00000317336; = p.T444M on NM_020729.3) | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs748487219, COSV54013448; called by muse, mutect2, varscan2
- OR6X1 | c.97del p.Y33Tfs*3 | Frame Shift Del (DEL) | VAF 378/643 reads (59%) | catalogued as COSV60009960; called by pindel, varscan2
- PAK3 | c.1062G>T p.W354C (on ENST00000262836 / NM_001324328.2; = p.W339C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 629/1615 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53276184; called by muse, mutect2, varscan2
- PCDHB5 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1182162920, COSV50655601; called by muse, mutect2, varscan2
- PCDHGC3 | c.2050dup p.R684Pfs*41 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | catalogued as rs764598056; called by mutect2, varscan2
- PJA2 | c.138A>C p.K46N | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV63273370; called by muse, mutect2, varscan2
- PRODH2 | c.621C>A p.N207K (on ENST00000301175; = p.N131K on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs374226189, COSV56560339; called by muse, mutect2, varscan2
- PTGFR | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66114636, COSV66115438; called by muse, mutect2, varscan2
- RPE65 | c.940C>G p.H314D | Missense Mutation (SNP) | VAF 219/483 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52016760; called by muse, mutect2, varscan2
- RPS6KC1 | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 194/434 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100873834; called by muse, mutect2, varscan2
- SLC4A11 | c.203T>A p.F68Y | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.516); catalogued as COSV66262426; called by muse, mutect2, varscan2
- SMS | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 342/885 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65114535; called by muse, mutect2, varscan2
- SPTBN1 | c.5654G>A p.R1885H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs767197512; called by muse, mutect2, varscan2
- STAU1 | c.1076C>T p.A359V (on ENST00000371856 / NM_001319135.1; = p.A278V on NM_004602.3) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs756552022, COSV61460763; called by muse, mutect2, varscan2
- STK38L | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as rs1436693470, COSV66521831, COSV66522980; called by muse, mutect2, varscan2
- TANC1 | c.4252A>T p.K1418* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV55089975; called by muse, mutect2, varscan2
- TEX101 | c.207A>T p.A69= (on ENST00000598265 / NM_001130011.3; = p.A87= on NM_031451.4) | Splice Region (SNP) | VAF 70/86 reads (81%) | catalogued as COSV53662265; called by muse, mutect2, varscan2
- TNS4 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 63/79 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54185771; called by muse, mutect2, varscan2
- TRIM63 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as COSV65328740; called by muse, mutect2, varscan2
- TRPV5 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 131/350 reads (37%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.533); catalogued as COSV54687034; called by muse, mutect2, varscan2
- TTBK2 | c.2254C>G p.Q752E | Missense Mutation (SNP) | VAF 364/917 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.078); catalogued as COSV51165134, COSV99142358; called by muse, mutect2, varscan2
- TYK2 | c.3315dup p.T1106Hfs*5 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | catalogued as rs757101286; called by mutect2, varscan2
- UHRF1BP1 | c.1622T>C p.M541T | Missense Mutation (SNP) | VAF 54/558 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV51961575; called by muse, mutect2
- WFIKKN2 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 119/123 reads (97%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs562619882, COSV60959183; called by muse, mutect2, varscan2
- WNT7A | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as rs1489800790, COSV53199767; called by muse, mutect2, varscan2
- YWHAE | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV51983240, COSV51984459; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 9/54 reads (17%) | catalogued as rs761578656; called by mutect2, varscan2
- ZMYM1 | c.182C>G p.T61S | Missense Mutation (SNP) | VAF 227/532 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100720943; called by muse, mutect2, varscan2
- ZNF552 | c.1157A>G p.E386G | Missense Mutation (SNP) | VAF 72/638 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66971642, COSV66971781; called by muse, mutect2, varscan2
- AC104452.1 | c.1271-17_1290del p.X424_splice | Splice Site (DEL) | VAF 83/227 reads (37%) | called by mutect2, pindel
- ADCY3 | c.2125_2149del p.A709* | Frame Shift Del (DEL) | VAF 28/164 reads (17%) | called by mutect2, pindel
- ADGRV1 | c.8801C>T p.S2934L | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- CUL9 | c.62_105del p.Y21Sfs*2 | Frame Shift Del (DEL) | VAF 61/202 reads (30%) | called by mutect2, pindel
- DCAF4L2 | c.-5_1del | Translation Start Site (DEL) | VAF 16/24 reads (67%) | called by mutect2, pindel, varscan2
- DHX30 | c.3192-13_3198del p.X1064_splice (on ENST00000445061 / NM_138615.3; = p.X1025_splice on NM_014966.3) | Splice Site (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- FOXJ2 | c.182_189del p.V61Gfs*35 | Frame Shift Del (DEL) | VAF 104/284 reads (37%) | called by mutect2, pindel, varscan2
- GET3 | c.551_562del p.E184_L187del | In Frame Del (DEL) | VAF 43/125 reads (34%) | called by mutect2, pindel, varscan2
- KIF1C | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2
- KIRREL3 | c.2050_2058del p.G684_G686del | In Frame Del (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
- LIN7A | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MUC16 | c.2967_2981del p.S991_T995del | In Frame Del (DEL) | VAF 707/1078 reads (66%) | called by mutect2, pindel, varscan2
- MYO3B | c.1193_1222del p.R398_S407del | In Frame Del (DEL) | VAF 144/493 reads (29%) | called by mutect2, pindel
- NPC1L1 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2
- OR1S1 | c.71_79delinsGGTT p.E24Gfs*10 | Frame Shift Del (DEL) | VAF 37/164 reads (23%) | called by pindel, varscan2*
- OR2T27 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OTUD5 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PRKCQ | c.1025_1043del p.Q342Lfs*17 | Frame Shift Del (DEL) | VAF 181/651 reads (28%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.851); called by muse, mutect2
- UNC79 | c.2492_2542del p.I831_H847del (on ENST00000393151 / NM_001346218.2; = p.I654_H670del on NM_020818.5) | In Frame Del (DEL) | VAF 160/222 reads (72%) | called by mutect2, pindel
- ZFC3H1 | c.4747G>C p.A1583P | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZNF7 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF718 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ABCB5 | c.706T>C p.L236= | Silent (SNP) | VAF 22/446 reads (5%) | catalogued as COSV99327973; called by muse, mutect2
- ADGRE1 | c.2335A>C p.R779= | Silent (SNP) | VAF 286/348 reads (82%) | called by muse, mutect2, varscan2
- AMER1 | c.3093C>G p.G1031= | Silent (SNP) | VAF 172/419 reads (41%) | catalogued as COSV57662300; called by muse, mutect2, varscan2
- COL5A1 | c.2223A>T p.P741= | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as COSV65670468, COSV65675884; called by muse, mutect2, varscan2
- CUBN | c.1551T>C p.T517= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as COSV64718754; called by muse, mutect2, varscan2
- DLK1 | c.1140C>T p.D380= | Silent (SNP) | VAF 62/70 reads (89%) | catalogued as rs1555410480, COSV57991742; called by muse, mutect2, varscan2
- FSCN1 | c.1182C>T p.F394= | Silent (SNP) | VAF 27/33 reads (82%) | catalogued as COSV61017887; called by muse, mutect2, varscan2
- HAPLN3 | c.522C>T p.N174= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs781710759, COSV61362540; called by muse, mutect2, varscan2
- HSPBAP1 | c.342A>T p.P114= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV60242724; called by muse, mutect2, varscan2
- ILF3 | c.1509C>T p.S503= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV51559128; called by muse, mutect2, varscan2
- LAMA3 | c.3279C>G p.P1093= | Silent (SNP) | VAF 176/245 reads (72%) | catalogued as COSV58071359; called by muse, mutect2, varscan2
- LBR | c.1287C>G p.L429= | Silent (SNP) | VAF 30/260 reads (12%) | catalogued as rs770438975, COSV55289556; called by muse, mutect2
- LYG2 | c.237T>G p.P79= | Silent (SNP) | VAF 187/462 reads (40%) | catalogued as COSV60715930; called by muse, mutect2, varscan2
- NEBL | c.792G>T p.A264= | Silent (SNP) | VAF 62/161 reads (39%) | called by muse, mutect2, varscan2
- PDXDC1 | c.396A>G p.E132= | Silent (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- POLA1 | c.2964A>G p.K988= | Silent (SNP) | VAF 79/187 reads (42%) | catalogued as rs1252797604, COSV66887466; called by muse, mutect2, varscan2
- PRRC2A | c.5493C>T p.R1831= | Silent (SNP) | VAF 80/97 reads (82%) | catalogued as COSV52991823; called by muse, mutect2, varscan2
- SGSM1 | c.2319T>C p.H773= (on ENST00000400359 / NM_001039948.4; = p.H712= on NM_133454.3) | Silent (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2
- THBS1 | c.945T>A p.P315= | Silent (SNP) | VAF 91/232 reads (39%) | catalogued as COSV52952977; called by muse, mutect2, varscan2
- TTYH2 | c.1077C>T p.H359= | Silent (SNP) | VAF 87/95 reads (92%) | catalogued as COSV53911213; called by muse, mutect2, varscan2
- WFDC5 | c.141C>T p.D47= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV57217182; called by muse, mutect2, varscan2
- WNK1 | c.1266C>T p.Y422= | Silent (SNP) | VAF 292/676 reads (43%) | catalogued as rs780974617, COSV60036343; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZSCAN1 | c.507A>T p.A169= | Silent (SNP) | VAF 71/75 reads (95%) | catalogued as COSV56605497; called by muse, mutect2, varscan2
- MFSD4B | c.28-2001T>A | Intron (SNP) | VAF 87/213 reads (41%) | catalogued as COSV64348982; called by muse, mutect2, varscan2
